Gene-level copy-number profile of tumor specimen TCGA-HZ-8005-01A from TCGA case TCGA-HZ-8005, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.2 years (29,674 days).
Specimen TCGA-HZ-8005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.4e06e279-5f0d-4bf5-8659-67b8069050b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-8005-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a30cc612-1898-4020-a0aa-3d43f9f52e37

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 207; copy number 2: 7,134; copy number 3: 18,461; copy number 4: 18,902; copy number 5: 5,126; copy number 6: 7,351; copy number 7: 1,758; copy number 8: 660; copy number 11: 197; copy number 44: 1; copy number 45: 6; copy number 50: 2; copy number 52: 9; copy number 94: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-8005-01A-11D-2200-01): tumor purity 0.29, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 221 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,556,323–127,419,050, 1 gene, copy number 94 (within-gene range 2–94): PCAT1.
- chr8:127,072,694–127,742,951, 12 genes, copy number 52–94: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:129,415,949–129,484,142, 2 genes, copy number 52 (within-gene range 2–52): AC011257.1, MIR3686.
- chr8:130,595,299–130,655,712, 1 gene, copy number 44 (within-gene range 2–44): AC090987.1.
- chr8:133,325,997–133,571,940, 6 genes, copy number 45 (within-gene range 2–45): KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:133,644,598–133,668,701, 2 genes, copy number 50: AC090821.1, Metazoa_SRP.
- chr16:84,817,182–86,089,526, 44 genes, copy number 11: AC025280.3, CRISPLD2, AC025280.1, AC025280.2, LINC02176, ZDHHC7, KIAA0513, CIBAR2, LINC02139, AC026469.1, GSE1, AC092275.1, COX6CP16, LINC00311, MIR5093, AC092377.1, AC133540.1, AC092127.2, AC092127.1, RN7SL381P, GINS2, C16orf74, AC018695.6, AC018695.9, MIR1910, AC018695.2, EMC8, RNU1-103P, AC018695.4, AC018695.3, COX4I1, AC018695.5, AC018695.1, AC018695.8, AC018695.7, IRF8, MIR6774, AC092723.5, LINC02132, AC092723.4, AC092723.1, AC092723.3, AC092723.2, AC135012.1.
- chr16:86,434,830–90,222,851, 149 genes, copy number 11 (broad region; genes not listed).
- chr22:42,160,013–42,432,403, 4 genes, copy number 11 (within-gene range 2–11): TCF20, OGFRP1, LINC01315, NFAM1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
